Somatic mutation profile of tumor specimen 0DNWKT from CCDI case PBCBUJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Solid pseudopapillary tumor; Tissue or organ of origin: Pancreas, NOS; Age at diagnosis: 15.0 years (5,488 days).
Specimen 0DNWKT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 380b1017-fe35-450b-a3d4-0e59e9dde04c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNWJG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e48e38a-1de3-4d35-8610-da657e0b1395

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 7, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 314/719 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- EPB41L3 | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 40/734 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1350949619, COSV59447862; called by muse, mutect2
- NCOA7 | c.1499C>T p.S500F | Missense Mutation (SNP) | VAF 36/674 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.086); catalogued as rs778729370; called by muse, mutect2
- OVOL1 | c.685G>A p.V229I | Missense Mutation (SNP) | VAF 48/648 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs142294960; called by muse, mutect2
- COL5A1 | c.4529G>T p.G1510V | Missense Mutation (SNP) | VAF 66/1100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PIK3C2A | c.3388G>A p.G1130R | Missense Mutation (SNP) | VAF 115/358 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POU2F1 | c.2050C>G p.L684V (on ENST00000541643 / NM_001365848.1; = p.L707V on NM_002697.4) | Missense Mutation (SNP) | VAF 71/520 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- LACTBL1 | c.354G>A p.P118= (on ENST00000618559; = p.P147= on NM_001289974.2) | Silent (SNP) | VAF 36/732 reads (5%) | catalogued as rs957277796, COSV101382408; called by muse, mutect2
- MROH2B | c.1974A>G p.G658= | Silent (SNP) | VAF 38/772 reads (5%) | called by muse, mutect2
- RYR1 | c.1038C>T p.F346= | Silent (SNP) | VAF 40/452 reads (9%) | catalogued as rs1333206146; ClinVar: likely benign; called by muse, mutect2
- SLC27A2 | c.756C>T p.S252= | Silent (SNP) | VAF 93/1028 reads (9%) | catalogued as rs529162625, COSV99982847; called by muse, mutect2
- TRPM5 | c.1233G>T p.T411= | Silent (SNP) | VAF 74/1230 reads (6%) | called by muse, mutect2
